Somatic mutation profile of tumor specimen TARGET-10-PAUACG-09A (aliquot TARGET-10-PAUACG-09A-01D) from TARGET case TARGET-10-PAUACG, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.9 years (1,807 days).
Specimen TARGET-10-PAUACG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ca61e81-16ed-471e-90b4-7f02bc76d9b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAUACG-10A (Blood Derived Normal), aliquot TARGET-10-PAUACG-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f71dcc72-4d8a-4a1e-ab7a-937009665288

The open-access MAF lists 20 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, Nonsense Mutation 2, RNA 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.663_664insT p.D222* | Frame Shift Ins (INS) | VAF 48/165 reads (29%) | catalogued as COSV50550500; called by mutect2, pindel, varscan2
- DNM2 | c.2308C>T p.R770* (on ENST00000355667 / NM_001005360.3; = p.R766* on NM_004945.3) | Nonsense Mutation (SNP) | VAF 39/87 reads (45%) | catalogued as COSV53033391; called by muse, mutect2, varscan2
- NOTCH1 | c.4757G>C p.R1586P | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.845); catalogued as COSV53047710; called by muse, mutect2, varscan2
- PLCB1 | c.2227G>A p.A743T | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV62073563; called by muse, mutect2, varscan2
- PPP6R2 | c.1815C>A p.F605L (on ENST00000216061 / NM_001365836.1; = p.F578L on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV53300682; called by muse, mutect2, varscan2
- THSD7A | c.1098G>A p.W366* | Nonsense Mutation (SNP) | VAF 20/79 reads (25%) | catalogued as COSV70275773; called by muse, mutect2, varscan2
- TIGD5 | c.1247C>G p.P416R | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55309835; called by muse, mutect2, varscan2
- TOR4A | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs779234181, COSV62627832; called by muse, varscan2
- UNCX | c.503A>G p.K168R | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs768124844; called by mutect2, varscan2
- AKAP12 | c.1396C>A p.L466I | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2
- PER1 | c.498G>T p.Q166H | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2
- SIPA1L2 | c.1304G>T p.S435I | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.197); called by muse, mutect2
- UMODL1 | c.2686C>A p.Q896K (on ENST00000408910 / NM_001004416.2; = p.Q1024K on NM_173568.3) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.05); called by muse, mutect2
- CHRNA5 | c.468C>A p.G156= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- GAP43 | c.327C>T p.S109= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs773971941, COSV59343857; called by muse, mutect2, varscan2
- NPHS1 | c.3180G>T p.L1060= | Silent (SNP) | VAF 47/87 reads (54%) | catalogued as rs772583245, COSV62290034; called by muse, mutect2, varscan2
- RANBP2 | c.9271C>A p.R3091= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV51699779; called by muse, mutect2
- TGFBR3 | c.75T>C p.G25= | Silent (SNP) | VAF 31/84 reads (37%) | called by muse, mutect2, varscan2
- MIR520D | n.78C>T | RNA (SNP) | VAF 19/61 reads (31%) | catalogued as rs747353189; called by muse, varscan2
- SNORA71E | n.26C>A | RNA (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
